Somatic mutation profile of tumor specimen TCGA-DA-A95X-06A (aliquot TCGA-DA-A95X-06A-11D-A372-08) from TCGA case TCGA-DA-A95X, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.2 years (23,831 days).
Specimen TCGA-DA-A95X-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3aa72a78-0088-4a40-b90e-056b88f76acd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A95X-10A (Blood Derived Normal), aliquot TCGA-DA-A95X-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10809bfe-f61e-4329-ab42-d9dde3a6d124

The open-access MAF lists 615 somatic variants for this specimen: 425 protein-altering or splice-affecting, 173 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 391, Silent 173, Nonsense Mutation 25, Intron 6, RNA 6, Splice Site 4, 5'UTR 3, Splice Region 3, 3'UTR 1, Frame Shift Del 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 68/152 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3574C>T p.R1192C | Missense Mutation (SNP) | VAF 25/71 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568509370, COSV60787617, COSV60789344; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 22/28 reads (79%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.3052C>T p.R1018* (on ENST00000404938 / NM_001163941.2; = p.R573* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 53/62 reads (85%) | catalogued as rs200343372; called by muse, mutect2, varscan2
- ABCC6 | c.2029C>T p.L677F | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52747395; called by muse, mutect2, varscan2
- ABCC8 | c.3820G>C p.E1274Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as COSV56856589; called by muse, mutect2, varscan2
- ABHD2 | c.359A>T p.H120L | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV61775947; called by muse, mutect2, varscan2
- ACP6 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (1); PolyPhen possibly damaging (0.713); catalogued as COSV65077837; called by muse, mutect2, varscan2
- ACTRT2 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.966); catalogued as rs766249662, COSV65760350; called by muse, mutect2, varscan2
- ADAM30 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as COSV65560479; called by muse, mutect2, varscan2
- ADAMTS6 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 60/87 reads (69%) | SIFT tolerated (0.82); PolyPhen benign (0.363); catalogued as rs574046720, COSV58681823; called by muse, mutect2, varscan2
- ADCY4 | c.3082G>A p.V1028M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60254255, COSV60257238; called by muse, mutect2, varscan2
- ADGRF1 | c.1850G>A p.S617N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51947379; called by muse, mutect2, varscan2
- ADGRV1 | c.9793G>A p.E3265K | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs1561602672, COSV67981178; called by muse, mutect2, varscan2
- AHNAK | c.17509G>A p.E5837K | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV57227661; called by muse, mutect2, varscan2
- AKR1C4 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.337); catalogued as COSV54123578; called by muse, mutect2, varscan2
- ALDH1L2 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as COSV51559321; called by muse, mutect2, varscan2
- AMPD1 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs762251657, COSV62418363; called by muse, mutect2, varscan2
- ANK3 | c.5986G>A p.E1996K | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs770259969, COSV55067940, COSV55079093; called by muse, mutect2, varscan2
- ANK3 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs1439725342; called by muse, mutect2, varscan2
- ANKEF1 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV65693512; called by muse, mutect2, varscan2
- ANO5 | c.230T>C p.I77T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV61089670; called by muse, mutect2, varscan2
- ANPEP | c.2320G>A p.G774S | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs374584607; called by muse, mutect2, varscan2
- AOC3 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs1230717527, COSV53828553; called by muse, mutect2, varscan2
- APOB | c.11690C>T p.T3897I | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs750179992, COSV51949950; called by muse, mutect2, varscan2
- APOH | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1230677675, COSV52774770, COSV52775239; called by muse, mutect2, varscan2
- ARHGAP26 | c.2312A>C p.H771P | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99188765; called by muse, mutect2, varscan2
- ARHGAP26 | c.2313T>A p.H771Q | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1280395053, COSV99188773; called by muse, mutect2, varscan2
- ARHGAP31 | c.3869C>T p.P1290L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1373109639, COSV51798137; called by muse, mutect2, varscan2
- ARHGAP4 | c.308G>T p.W103L | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100603729; called by muse, mutect2, varscan2
- ARHGAP6 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV57298523; called by muse, mutect2, varscan2
- ARIH2 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV62706135; called by muse, mutect2, varscan2
- ARMC4 | c.3038T>G p.V1013G | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59472369; called by muse, mutect2, varscan2
- ARMC5 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51654867, COSV99192299; called by muse, mutect2, varscan2
- ATP2A2 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100428330; called by muse, mutect2, varscan2
- AXDND1 | c.1770A>T p.E590D | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV62647516; called by muse, mutect2, varscan2
- AXDND1 | c.1927A>T p.K643* | Nonsense Mutation (SNP) | VAF 26/75 reads (35%) | catalogued as COSV62647524; called by muse, mutect2, varscan2
- BAALC | c.305G>A p.R102Q (on ENST00000297574 / NM_001364874.1; = p.R67Q on NM_024812.3) | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.478); catalogued as rs200984161; called by muse, mutect2, varscan2
- BBOX1 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV99589376; called by muse, mutect2, varscan2
- BHMT2 | c.423G>A p.W141* | Nonsense Mutation (SNP) | VAF 37/87 reads (43%) | catalogued as rs1466937238, COSV54874574; called by muse, mutect2, varscan2
- BMS1 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs1409791902, COSV65735267; called by muse, mutect2, varscan2
- BRSK1 | c.1047G>A p.M349I | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV58665814; called by muse, varscan2
- BSND | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.177); catalogued as COSV64871324; called by muse, mutect2, varscan2
- BTBD16 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs144981513, COSV53266635; called by muse, mutect2, varscan2
- C10orf71 | c.586A>G p.R196G | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV60512093; called by muse, mutect2, varscan2
- C14orf39 | c.1694C>T p.S565L | Missense Mutation (SNP) | VAF 100/256 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1322882418, COSV58784626; called by muse, mutect2, varscan2
- C1orf94 | c.1711C>T p.Q571* (on ENST00000488417 / NM_001134734.2; = p.Q381* on NM_032884.5) | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as COSV64915475; called by muse, mutect2, varscan2
- CACNA1D | c.3277G>T p.A1093S (on ENST00000350061 / NM_001128840.3; = p.A1113S on NM_000720.4) | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.587); catalogued as COSV55462673; called by muse, mutect2, varscan2
- CACNA1D | c.5204C>T p.S1735L (on ENST00000350061 / NM_001128840.3; = p.S1755L on NM_000720.4) | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs1461261149, COSV55437928; called by muse, mutect2, varscan2
- CACNA2D1 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as COSV62390610; called by muse, mutect2, varscan2
- CAMK1D | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66618727; called by muse, mutect2, varscan2
- CAMSAP3 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.826); catalogued as rs375671131; called by muse, mutect2, varscan2
- CARD14 | c.2198G>A p.G733D | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1458775691, COSV60126362; called by muse, mutect2, varscan2
- CATSPERB | c.2855C>T p.P952L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56433589; called by muse, mutect2, varscan2
- CATSPERB | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56433613; called by muse, mutect2, varscan2
- CCAR2 | c.1631T>G p.F544C | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52386374; called by muse, mutect2, varscan2
- CCM2L | c.1139G>A p.G380D (on ENST00000452892 / NM_001365692.1; = p.A359T on NM_080625.4) | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as COSV52952319; called by muse, mutect2, varscan2
- CD19 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 16/29 reads (55%) | catalogued as COSV100217988; called by muse, mutect2, varscan2
- CD6 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57836499; called by muse, mutect2
- CDC123 | c.845A>G p.Q282R | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.139); catalogued as COSV55399675; called by muse, mutect2, varscan2
- CDH23 | c.8449C>T p.P2817S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV56485985; called by muse, mutect2, varscan2
- CDH6 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV54065131, COSV54077032; called by muse, mutect2, varscan2
- CDON | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV55001853; called by muse, mutect2, varscan2
- CEP164 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.515); catalogued as COSV54041396; called by muse, mutect2, varscan2
- CHST15 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60565267; called by muse, mutect2, varscan2
- CHSY3 | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59286644; called by muse, mutect2, varscan2
- CLCA4 | c.997T>A p.F333I | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55370693; called by muse, mutect2, varscan2
- CLIP4 | c.1234A>T p.K412* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV60752148; called by muse, mutect2, varscan2
- CMKLR1 | c.563C>T p.S188F (on ENST00000312143 / NM_001142344.2; = p.S186F on NM_004072.3) | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.71); PolyPhen benign (0.043); catalogued as COSV56441569; called by muse, mutect2, varscan2
- CNIH1 | c.112T>C p.Y38H | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.958); catalogued as COSV53595058; called by muse, mutect2, varscan2
- CNTN4 | c.2387C>T p.S796F | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV61879981; called by muse, mutect2, varscan2
- CNTNAP3 | c.2413C>T p.H805Y | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV99903891; called by muse, mutect2, varscan2
- COL13A1 | c.2036G>A p.G679E (on ENST00000398978 / NM_001130103.2; = p.G607E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1321833159, COSV62574335; called by muse, mutect2, varscan2
- COL5A1 | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as rs971542908, COSV100879329; called by muse, mutect2, varscan2
- COL5A1 | c.5413C>T p.P1805S | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.596); catalogued as rs554332661, COSV65666320; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A2 | c.1438G>C p.G480R | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66414266; called by muse, mutect2, varscan2
- COPB1 | c.702C>T p.V234= | Splice Region (SNP) | VAF 47/136 reads (35%) | catalogued as COSV51450459; called by muse, mutect2, varscan2
- COX7A2L | c.31A>T p.K11* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV52243915; called by muse, mutect2, varscan2
- CR2 | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs1358947848, COSV65509409; called by muse, mutect2
- CRB1 | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs986645649, COSV66328552; called by muse, mutect2, varscan2
- CSMD1 | c.8626T>A p.F2876I (on ENST00000520002; = p.F2875I on NM_033225.6) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV59374803; called by muse, mutect2, varscan2
- CSMD3 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs755471454, COSV52241436; called by muse, mutect2, varscan2
- CTAGE1 | c.1631G>A p.G544E | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV66943892, COSV66945275; called by muse, mutect2, varscan2
- CUZD1 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0.185); catalogued as COSV59026725; called by muse, mutect2, varscan2
- CYB561A3 | c.688A>T p.I230F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV53653716; called by muse, varscan2
- CYLC1 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100253896, COSV61412186; called by muse, mutect2, varscan2
- CYP3A4 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV60503912; called by muse, mutect2, varscan2
- DAB1 | c.1034G>A p.G345D (on ENST00000371231; = p.G312D on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs377760284; called by muse, mutect2, varscan2
- DCC | c.3705G>A p.M1235I | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV71439833; called by muse, mutect2, varscan2
- DCDC1 | c.3609A>T p.K1203N (on ENST00000597505 / NM_001367979.1; = p.K310N on NM_020869.3) | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV60311804; called by muse, mutect2, varscan2
- DCDC1 | c.2383G>A p.G795S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.415); catalogued as rs1290941768, COSV100662521; called by muse, mutect2, varscan2
- DCDC1 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs776704634, COSV60835487; called by muse, mutect2, varscan2
- DCLK1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1366698690, COSV55170182; called by muse, mutect2, varscan2
- DDHD1 | c.430A>G p.S144G (on ENST00000323669; = p.S341G on NM_030637.3) | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs1317416387, COSV60362222; called by muse, mutect2, varscan2
- DEFA3 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100590589; called by muse, mutect2, varscan2
- DENND1A | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.207); catalogued as COSV65355352; called by muse, mutect2, varscan2
- DENND4C | c.4505C>T p.P1502L (on ENST00000434457 / NM_001330640.2; = p.P1453L on NM_017925.7) | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV63009704; called by muse, mutect2, varscan2
- DGKB | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 10/12 reads (83%) | catalogued as COSV51814235; called by muse, mutect2, varscan2
- DGKG | c.465A>T p.E155D | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV53971504; called by muse, mutect2, varscan2
- DHDH | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 48/66 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as rs35307000, COSV55483277; called by muse, mutect2, varscan2
- DHX35 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1244706130, COSV52673804; called by muse, mutect2, varscan2
- DIDO1 | c.2465C>T p.P822L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV56632862; called by muse, mutect2, varscan2
- DIPK1B | c.866C>A p.S289Y | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV63038272; called by muse, mutect2, varscan2
- DISP3 | c.1589-1G>A p.X530_splice | Splice Site (SNP) | VAF 10/27 reads (37%) | catalogued as COSV53836172, COSV99610414; called by muse, mutect2, varscan2
- DNAH10 | c.1261G>T p.V421F (on ENST00000409039; = p.V360F on NM_207437.3) | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV69000163; called by muse, mutect2, varscan2
- DNAH3 | c.5026G>A p.D1676N | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV54547046; called by muse, mutect2, varscan2
- DNAH5 | c.10577C>T p.A3526V | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs765488703, COSV54248036; called by muse, mutect2, varscan2
- DNAH7 | c.5651G>A p.R1884Q | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs201751336; called by muse, mutect2, varscan2
- DNAH8 | c.11485C>T p.R3829C | Missense Mutation (SNP) | VAF 118/203 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs751189468, COSV59472138, COSV59483431; called by muse, mutect2, varscan2
- DNAH8 | c.12191G>A p.R4064Q | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327466194, COSV59421605; called by muse, mutect2, varscan2
- DNAI4 | c.1863G>A p.W621* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | catalogued as COSV64023455; called by muse, mutect2, varscan2
- DPEP3 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as rs142825117; called by muse, mutect2, varscan2
- DSC3 | c.2065G>A p.G689R | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64575105; called by muse, mutect2, varscan2
- DSCAM | c.4309C>T p.R1437C | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757906374, COSV68028777; called by muse, mutect2, varscan2
- DSCAML1 | c.5008T>C p.F1670L (on ENST00000321322; = p.F1610L on NM_020693.4) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.328); catalogued as COSV58401329; called by muse, mutect2, varscan2
- DSG4 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759072801, COSV57396819; called by muse, mutect2, varscan2
- DUOX2 | c.4555C>T p.P1519S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66532254; called by muse, mutect2, varscan2
- DYNC2H1 | c.11896C>T p.P3966S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as rs1353307673, COSV62104945; called by muse, mutect2, varscan2
- EBNA1BP2 | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.871); catalogued as COSV52541372; called by muse, mutect2, varscan2
- ECE1 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV51669797; called by muse, mutect2, varscan2
- EFS | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV52837202; called by muse, mutect2, varscan2
- EGFLAM | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as COSV59297844; called by muse, mutect2, varscan2
- EHD3 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV59032707, COSV59032997; called by muse, mutect2, varscan2
- ELAPOR1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs753845146, COSV64043939; called by muse, mutect2, varscan2
- ELL2 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52984906; called by muse, mutect2, varscan2
- ERC2 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 32/61 reads (52%) | catalogued as COSV55604361; called by muse, mutect2, varscan2
- ERICH3 | c.3303A>T p.E1101D | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV100443123; called by muse, mutect2, varscan2
- ETS1 | c.940C>T p.L314F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV60097068; called by muse, mutect2, varscan2
- EVPL | c.3661G>C p.A1221P | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as COSV56915134; called by muse, mutect2, varscan2
- F13B | c.1927T>A p.Y643N | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66375508; called by muse, mutect2, varscan2
- FAM135B | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1487707765, COSV52749613; called by muse, varscan2
- FAM83B | c.1400T>A p.F467Y | Missense Mutation (SNP) | VAF 71/115 reads (62%) | SIFT tolerated (0.49); PolyPhen benign (0.1); catalogued as COSV60926138; called by muse, mutect2, varscan2
- FAP | c.1262G>A p.R421K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0.169); catalogued as rs1483844612, COSV51866825; called by muse, mutect2, varscan2
- FAT4 | c.13286C>T p.P4429L | Missense Mutation (SNP) | VAF 73/97 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs866550480, COSV58705056; called by muse, mutect2, varscan2
- FBN1 | c.7901C>T p.P2634L | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57328349; called by muse, mutect2, varscan2
- FCGBP | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs747176936; called by muse, mutect2, varscan2
- FCSK | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55374840; called by muse, mutect2, varscan2
- FLI1 | c.1133T>A p.M378K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as COSV55647361; called by muse, varscan2
- FLI1 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV55647371; called by muse, varscan2
- FLNC | c.7399C>T p.R2467C | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.982); catalogued as rs1278916117, COSV57963530; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNDC3B | c.3080C>T p.S1027F | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.285); catalogued as rs1340224917, COSV100393394; called by muse, mutect2, varscan2
- FREM2 | c.7981C>T p.Q2661* | Nonsense Mutation (SNP) | VAF 25/32 reads (78%) | catalogued as COSV54849967; called by muse, mutect2
- FRMPD2 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1291470850, COSV100563416; called by muse, mutect2, varscan2
- FRMPD2 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs868480565, COSV59718954; called by muse, mutect2, varscan2
- FUT3 | c.850T>G p.F284V | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as COSV99744170; called by muse, mutect2, varscan2
- FYB2 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.898); catalogued as COSV58582681; called by muse, mutect2, varscan2
- GABRB2 | c.1276G>A p.D426N (on ENST00000274547; = p.D388N on NM_000813.3) | Missense Mutation (SNP) | VAF 45/61 reads (74%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.735); catalogued as COSV50938523; called by muse, mutect2, varscan2
- GALNT13 | c.690A>T p.K230N | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as COSV67236146; called by muse, mutect2, varscan2
- GCNT3 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as rs779195697, COSV68532477; called by muse, mutect2, varscan2
- GDF5 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs771055628, COSV65499127; called by muse, mutect2, varscan2
- GJB4 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); catalogued as rs1557652270, COSV100258214; called by muse, mutect2, varscan2
- GOLGA2 | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 116/160 reads (73%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as rs771851290, COSV57855600; called by muse, mutect2, varscan2
- GOLGA4 | c.3106C>A p.H1036N | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774662455, COSV62713443; called by muse, mutect2, varscan2
- GPR174 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV52134095; called by muse, mutect2, varscan2
- GRIA2 | c.1087G>T p.D363Y | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1295274619, COSV52403594; called by muse, mutect2, varscan2
- GRN | c.600G>A p.V200= | Splice Region (SNP) | VAF 22/28 reads (79%) | catalogued as COSV50008740; called by muse, mutect2, varscan2
- GTF3C4 | c.1832C>T p.S611L | Missense Mutation (SNP) | VAF 54/73 reads (74%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as rs1050022135, COSV64645003; called by muse, mutect2, varscan2
- GUSB | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 66/74 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV59223546; called by muse, mutect2, varscan2
- HAUS6 | c.2722T>C p.S908P | Missense Mutation (SNP) | VAF 71/96 reads (74%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV65840736; called by muse, mutect2, varscan2
- HBD | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.632); catalogued as rs1330904300, CM164902, CM963017, COSV53083013; called by muse, mutect2, varscan2
- HERC2 | c.5788G>A p.E1930K | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.245); catalogued as COSV55346343; called by muse, mutect2, varscan2
- HGD | c.255G>A p.W85* | Nonsense Mutation (SNP) | VAF 36/75 reads (48%) | catalogued as rs1291206526, COSV52200978, COSV99380683; called by muse, mutect2, varscan2
- HID1 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV59352237; called by muse, mutect2, varscan2
- HLA-DRA | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100895032; called by muse, mutect2, varscan2
- HMGB3 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 122/143 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57486037; called by muse, mutect2, varscan2
- HP1BP3 | c.1160C>T p.T387I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56564436; called by muse, mutect2, varscan2
- HS1BP3 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV58314805; called by muse, mutect2
- HSPA4L | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141362649; called by muse, mutect2, varscan2
- HSPB8 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as rs774648716, COSV99931108; ClinVar: likely benign; called by muse, mutect2, varscan2
- ICE1 | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 25/37 reads (68%) | catalogued as COSV56831295; called by muse, mutect2, varscan2
- IGHV3-21 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 66/254 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs1555459242; called by muse, mutect2, varscan2
- IL4I1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as rs754061983, COSV62011876; called by muse, mutect2, varscan2
- ITGB2 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100185510; called by muse, mutect2
- IVNS1ABP | c.369T>A p.D123E | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV62250290; called by muse, mutect2, varscan2
- JCAD | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64761412; called by muse, mutect2, varscan2
- JMJD1C | c.5938C>T p.P1980S | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV59517573; called by muse, mutect2, varscan2
- KCNH5 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs150842380; called by muse, mutect2, varscan2
- KCNH5 | c.1055T>G p.L352R | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100525024; called by muse, mutect2, varscan2
- KCNK1 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64034578; called by muse, mutect2, varscan2
- KDM3B | c.4896T>C p.V1632= | Splice Region (SNP) | VAF 25/44 reads (57%) | catalogued as COSV58694574; called by muse, mutect2, varscan2
- KDM6B | c.2030C>T p.P677L | Missense Mutation (SNP) | VAF 63/88 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.894); catalogued as rs545723280, COSV99640587; called by muse, mutect2, varscan2
- KEL | c.1074-2A>G p.X358_splice | Splice Site (SNP) | VAF 37/44 reads (84%) | catalogued as rs1330297663, COSV62337429; called by muse, mutect2, varscan2
- KEL | c.347A>T p.N116I | Missense Mutation (SNP) | VAF 95/115 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV62337437; called by muse, mutect2, varscan2
- KIAA0319L | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV57849935; called by muse, mutect2, varscan2
- KIAA1210 | c.4367G>A p.G1456D | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (0.32); PolyPhen benign (0.083); catalogued as COSV68179747; called by muse, mutect2, varscan2
- KLF17 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs141181356; called by muse, mutect2, varscan2
- KLHDC7A | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1216719846, COSV68768971; called by muse, mutect2, varscan2
- KLHL13 | c.837G>A p.M279I | Missense Mutation (SNP) | VAF 47/59 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as COSV53252349; called by muse, mutect2, varscan2
- KLHL4 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as COSV64147140; called by muse, mutect2, varscan2
- KLHL7 | c.1684C>T p.R562C (on ENST00000339077 / NM_001031710.3; = p.R514C on NM_018846.5) | Missense Mutation (SNP) | VAF 113/131 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV59161084; called by muse, mutect2, varscan2
- KRT7 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs148061330; called by muse, mutect2, varscan2
- LAMB3 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as rs746810833, COSV61919274; called by muse, mutect2, varscan2
- LATS1 | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 87/117 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53587276, COSV53598666; called by muse, mutect2, varscan2
- LEPR | c.2323A>G p.K775E | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs752069435, COSV60763124; called by muse, mutect2, varscan2
- LGR5 | c.1957T>A p.F653I | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV57009279; called by muse, mutect2, varscan2
- LPA | c.4564A>C p.T1522P | Missense Mutation (SNP) | VAF 80/104 reads (77%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV100305861; called by muse, mutect2, varscan2
- LPCAT2 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as rs1036948118, COSV50899170; called by muse, mutect2, varscan2
- LRBA | c.1188C>G p.S396R | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63963346; called by muse, mutect2, varscan2
- LRIT1 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.035); catalogued as COSV64513483; called by muse, mutect2, varscan2
- LTN1 | c.4682C>T p.P1561L | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV63735079; called by muse, mutect2, varscan2
- LYZL4 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV55105067; called by muse, mutect2, varscan2
- MAGI3 | c.2269C>T p.P757S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs531377931, COSV56843206; called by muse, mutect2, varscan2
- MBD1 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.98); PolyPhen benign (0.015); catalogued as rs1203312724, COSV54006367; called by muse, mutect2, varscan2
- MBD6 | c.2458T>C p.S820P | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV63076271; called by muse, mutect2, varscan2
- MCTP1 | c.1388G>A p.R463K | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.625); catalogued as rs1447160436, COSV56530842; called by muse, mutect2, varscan2
- MCTP1 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56512108, COSV56537723; called by muse, mutect2, varscan2
- MCTP2 | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV59147063; called by muse, mutect2, varscan2
- MECOM | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs758678191, COSV72110712; called by muse, mutect2, varscan2
- MED13 | c.4855C>T p.R1619W | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs762726170, COSV67266615; called by muse, mutect2, varscan2
- MINAR1 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV59586032; called by muse, mutect2, varscan2
- MRAS | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV56673787; called by muse, mutect2, varscan2
- MROH2B | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101270905, COSV68188772; called by muse, mutect2, varscan2
- MTAP | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 83/118 reads (70%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV101205369; called by muse, mutect2, varscan2
- MTOR | c.2942C>T p.S981F | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100815632; called by muse, mutect2, varscan2
- MUC5AC | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); catalogued as rs1250696382, COSV100650502; called by muse, mutect2, varscan2
- MUC5B | c.15425C>T p.S5142F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV101500150, COSV71594880; called by muse, mutect2, varscan2
- MVK | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV57332784; called by muse, mutect2, varscan2
- MYBPH | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as COSV55143997; called by muse, mutect2, varscan2
- MYCBP2 | c.9167C>T p.S3056L (on ENST00000357337; = p.S3094L on NM_015057.5) | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV62029437; called by muse, mutect2, varscan2
- MYLK | c.2198C>T p.S733F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.748); catalogued as COSV60620552; called by muse, mutect2, varscan2
- MYO15A | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as rs773996873, CM1410846, COSV52755337; called by muse, mutect2, varscan2
- NAV2 | c.3956C>T p.S1319F (on ENST00000396087 / NM_001244963.2; = p.S1296F on NM_145117.5) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1044154830, COSV60664424; called by muse, mutect2, varscan2
- NCF1 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.06); catalogued as rs1160867604; called by mutect2, varscan2
- NDN | c.633G>T p.W211C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100086163; called by muse, mutect2, varscan2
- NDN | c.632G>A p.W211* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100086165, COSV100086204; called by muse, mutect2, varscan2
- NDRG2 | c.268G>A p.E90K (on ENST00000298687 / NM_001354570.1; = p.E76K on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV53873513; called by muse, mutect2, varscan2
- NECTIN4 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as rs1225809043, COSV100919789; called by muse, mutect2, varscan2
- NEK9 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53133286; called by muse, mutect2, varscan2
- NEUROG3 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54342335; called by muse, mutect2, varscan2
- NF1 | c.2557C>T p.Q853* | Nonsense Mutation (SNP) | VAF 19/27 reads (70%) | catalogued as CM1311463, COSV62207579; called by muse, mutect2, varscan2
- NLRC3 | c.2780A>C p.E927A | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57095259; called by muse, mutect2, varscan2
- NLRP1 | c.807G>A p.W269* | Nonsense Mutation (SNP) | VAF 63/179 reads (35%) | catalogued as COSV52568846; called by muse, mutect2, varscan2
- NMUR2 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 55/72 reads (76%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV54919103; called by muse, mutect2, varscan2
- NPHS2 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752360023, CD000615, COSV62636408; called by muse, mutect2, varscan2
- NPHS2 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs74315345, CM000580, COSV62635220, COSV62635483; called by muse, varscan2
- NRXN2 | c.3100G>A p.D1034N | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs775962047, COSV55461858; called by muse, mutect2, varscan2
- NWD1 | c.934T>A p.F312I | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60350255; called by muse, mutect2, varscan2
- OBP2B | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.31); PolyPhen benign (0.167); catalogued as COSV100922801; called by muse, mutect2, varscan2
- ODF3L2 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV59623976; called by muse, mutect2, varscan2
- OLFM3 | c.363G>A p.M121I (on ENST00000338858 / NM_001288821.1; = p.M101I on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100129641, COSV58800718; called by muse, mutect2, varscan2
- OR10A5 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55055519; called by muse, mutect2, varscan2
- OR10G8 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1409052520, COSV70909333; called by muse, varscan2
- OR10Q1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as COSV57471845; called by muse, mutect2, varscan2
- OR1J4 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV61590241; called by muse, mutect2, varscan2
- OR2C3 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs201316551, COSV63574580; called by muse, mutect2, varscan2
- OR2G3 | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV60682928; called by muse, mutect2, varscan2
- OR2J2 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 185/311 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65848103; called by muse, mutect2, varscan2
- OR2M5 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 137/349 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs781595891, COSV63546287; called by muse, mutect2, varscan2
- OR3A3 | c.625T>A p.F209I | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52168446; called by muse, mutect2, varscan2
- OR4A16 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.208); catalogued as rs866883105, COSV59044837, COSV59044873; called by muse, mutect2, varscan2
- OR4N2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 63/305 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100269306; called by muse, mutect2, varscan2
- OR4Q3 | c.932G>A p.R311K | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV59180100; called by muse, mutect2, varscan2
- OR5M8 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59118049, COSV59118189; called by muse, mutect2, varscan2
- OR5W2 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV60617137, COSV60618122; called by muse, mutect2, varscan2
- OR6C76 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as COSV60389914; called by muse, mutect2, varscan2
- OR7D2 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); catalogued as COSV60139259; called by muse, mutect2, varscan2
- OR7G3 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV59640243; called by muse, mutect2, varscan2
- OR8H3 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs186768016, COSV57907283; called by muse, mutect2, varscan2
- ORC5 | c.1004T>G p.I335S | Missense Mutation (SNP) | VAF 52/59 reads (88%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.585); catalogued as rs773936634, COSV52402287; called by muse, mutect2, varscan2
- PANK1 | c.1178A>G p.N393S (on ENST00000307534 / NM_148977.2; = p.N168S on NM_138316.4) | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV56810225; called by muse, mutect2, varscan2
- PANK4 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1209119755, COSV65867818; called by muse, mutect2, varscan2
- PAPPA | c.3232C>T p.Q1078* | Nonsense Mutation (SNP) | VAF 19/23 reads (83%) | catalogued as COSV60290575; called by muse, mutect2, varscan2
- PATJ | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770908960, COSV100333139, COSV57170622; called by muse, mutect2, varscan2
- PAXBP1 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV51611912; called by muse, mutect2, varscan2
- PCDHA13 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV56479086; called by muse, mutect2, varscan2
- PCDHA3 | c.1499G>A p.G500E | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.393); catalogued as COSV63545435; called by muse, mutect2, varscan2
- PCDHA5 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.034); catalogued as COSV65352881; called by muse, mutect2, varscan2
- PCDHA8 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV65334627; called by muse, mutect2, varscan2
- PCDHGB4 | c.951G>C p.L317F | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV54018477; called by muse, mutect2, varscan2
- PDE6C | c.1702T>C p.F568L | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV101008499; called by muse, mutect2, varscan2
- PDS5A | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.37); PolyPhen benign (0.341); catalogued as COSV57830472; called by muse, mutect2, varscan2
- PELI1 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV62730795; called by muse, mutect2, varscan2
- PGLYRP3 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.202); catalogued as COSV51952483; called by muse, mutect2, varscan2
- PHLDA1 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56998116; called by muse, mutect2, varscan2
- PIGG | c.2326G>C p.D776H (on ENST00000453061 / NM_001127178.3; = p.D768H on NM_017733.4) | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV56321664; called by muse, mutect2
- PLCB4 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53798533, COSV99595264; called by muse, mutect2, varscan2
- PLCE1 | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.882); catalogued as rs771124727, COSV53337446; called by muse, mutect2, varscan2
- PLCH1 | c.875C>T p.P292L (on ENST00000340059 / NM_001130960.2; = p.P304L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1469074557, COSV58208697; called by muse, mutect2, varscan2
- PLCH2 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV53948725; called by muse, mutect2, varscan2
- PLCZ1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs1442862540, COSV56848602; called by muse, mutect2, varscan2
- PLEC | c.10924C>T p.P3642S (on ENST00000322810 / NM_201380.4; = p.P3532S on NM_000445.5) | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as COSV100509302; called by muse, mutect2, varscan2
- PLPPR1 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV66456979; called by muse, mutect2, varscan2
- POF1B | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.811); catalogued as COSV53139449, COSV99034891; called by muse, mutect2, varscan2
- POU2F1 | c.1079C>T p.S360L (on ENST00000541643 / NM_001365848.1; = p.S383L on NM_002697.4) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as rs755067431, COSV54812424; called by muse, mutect2, varscan2
- PPP1R13B | c.2393C>A p.S798Y | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV52448239, COSV52455745; called by muse, mutect2, varscan2
- PPP4R4 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58557700; called by muse, mutect2, varscan2
- PPP4R4 | c.2528G>A p.R843H | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs770949450, COSV58552888; called by muse, mutect2, varscan2
- PRCC | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV54858263; called by muse, mutect2, varscan2
- PRG2 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 84/185 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.227); catalogued as rs1283107232, COSV61294064; called by muse, mutect2, varscan2
- PRLR | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51499897; called by muse, mutect2, varscan2
- PRLR | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51499919; called by muse, mutect2, varscan2
- PRR16 | c.605G>A p.R202Q (on ENST00000407149 / NM_001300783.2; = p.R179Q on NM_016644.2) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs756220018, COSV65405069; called by muse, mutect2, varscan2
- PRSS58 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 113/138 reads (82%) | SIFT tolerated (0.53); PolyPhen benign (0.062); catalogued as COSV73488828; called by muse, mutect2, varscan2
- PSD | c.2408A>G p.K803R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV50043000; called by muse, mutect2
- PSG11 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 123/176 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60457545; called by muse, mutect2, varscan2
- PSMD2 | c.992T>G p.L331W | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV59531268; called by muse, mutect2, varscan2
- PTPN13 | c.4822G>A p.A1608T (on ENST00000411767 / NM_080683.3; = p.A1589T on NM_006264.3) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as rs1415139880, COSV100363866; called by muse, mutect2, varscan2
- PXDNL | c.3226G>A p.E1076K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs771432328, COSV62496490; called by muse, mutect2, varscan2
- QRICH2 | c.3734G>A p.R1245Q | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.711); catalogued as rs760928795, COSV53155023; called by muse, mutect2, varscan2
- R3HDM1 | c.2161C>T p.Q721* | Nonsense Mutation (SNP) | VAF 50/93 reads (54%) | catalogued as COSV51526008; called by muse, mutect2, varscan2
- RAB3C | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV51441458, COSV99277437; called by muse, mutect2, varscan2
- RAB3C | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV51441469; called by muse, mutect2, varscan2
- RABEPK | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.857); catalogued as rs76114327, COSV99413221; called by muse, mutect2, varscan2
- RAPGEF6 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV57254510; called by muse, mutect2, varscan2
- REEP2 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54735810; called by muse, mutect2, varscan2
- REST | c.2785C>T p.P929S | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV58362468; called by muse, mutect2, varscan2
- RFX6 | c.2434C>T p.H812Y | Missense Mutation (SNP) | VAF 50/66 reads (76%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV60588311; called by muse, mutect2, varscan2
- RGL1 | c.1225G>A p.D409N (on ENST00000360851 / NM_001297672.2; = p.D444N on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV58994777; called by muse, mutect2, varscan2
- RIN1 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.29); catalogued as COSV60926594; called by muse, mutect2, varscan2
- RLIM | c.1046C>A p.T349K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV100222782; called by muse, mutect2, varscan2
- RNF103 | c.1886A>G p.E629G | Missense Mutation (SNP) | VAF 81/161 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.138); catalogued as COSV52896722; called by muse, mutect2, varscan2
- RNF213 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 105/196 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1012522997, COSV60618683; called by muse, mutect2, varscan2
- RSRC1 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55829938; called by muse, mutect2, varscan2
- RTL3 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as rs148985625, COSV58183919; called by muse, mutect2, varscan2
- RTN1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.321); catalogued as rs140921136; called by muse, mutect2, varscan2
- SCUBE3 | c.1279C>G p.L427V | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV51460069; called by muse, mutect2, varscan2
- SDCBP | c.802A>G p.T268A | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV50699348; called by muse, mutect2, varscan2
- SDR16C5 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.259); catalogued as COSV58127363, COSV58128141; called by muse, mutect2, varscan2
- SEMA3F | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs769765430, COSV50028923; called by muse, mutect2, varscan2
- SEZ6L | c.2459C>T p.S820L | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs762219064, COSV50659948; called by muse, mutect2, varscan2
- SFXN5 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV55590118; called by muse, mutect2, varscan2
- SHANK2 | c.4570G>A p.G1524R | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV53616001; called by muse, mutect2, varscan2
- SIGLEC12 | c.1324G>A p.G442R (on ENST00000291707 / NM_053003.4; = p.G324R on NM_033329.2) | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV52464501; called by muse, mutect2, varscan2
- SIGLEC9 | c.182G>A p.W61* | Nonsense Mutation (SNP) | VAF 25/32 reads (78%) | catalogued as COSV51587651; called by muse, mutect2, varscan2
- SLC13A5 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs200209192, COSV99545595; called by muse, mutect2, varscan2
- SLC17A1 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs1466257436, COSV55081828; called by muse, varscan2
- SLC25A41 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV58600791; called by muse, mutect2, varscan2
- SLC2A1 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1553155891, COSV65288306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC45A4 | c.839T>A p.V280D (on ENST00000517878 / NM_001286646.2; = p.V229D on NM_001080431.2) | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV50175127; called by muse, mutect2, varscan2
- SLC52A3 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 26/62 reads (42%) | catalogued as COSV54079022; called by muse, mutect2, varscan2
- SLC5A7 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 161/360 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs768776054, COSV50901133; called by muse, mutect2, varscan2
- SLC5A7 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757121838, COSV50894235; called by muse, mutect2, varscan2
- SLC6A2 | c.646C>G p.R216G | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54922506; called by muse, mutect2, varscan2
- SLC9A2 | c.985C>T p.H329Y | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.983); catalogued as COSV52137001; called by muse, mutect2, varscan2
- SLC9A2 | c.1820G>A p.R607K | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV52131153, COSV52133766; called by muse, mutect2, varscan2
- SLC9C2 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as rs267598172, COSV62945331; called by muse, mutect2, varscan2
- SLFN11 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 24/33 reads (73%) | catalogued as COSV57700325; called by muse, mutect2, varscan2
- SNTG2 | c.1235G>A p.W412* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV100421628, COSV58003059; called by muse, mutect2, varscan2
- SNURF | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs371527962; called by muse, mutect2, varscan2
- SNX1 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs768722767, COSV56039870; called by muse, mutect2, varscan2
- SORCS3 | c.1082C>T p.T361I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV63822218; called by muse, mutect2, varscan2
- SPACA3 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs761929137, COSV52192493; called by muse, mutect2, varscan2
- SPEM1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV57211758; called by muse, mutect2, varscan2
- SPG11 | c.5851A>G p.R1951G | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV56001225; called by muse, mutect2, varscan2
- SPHKAP | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV60891954, COSV60895185; called by muse, mutect2, varscan2
- SPINK5 | c.35T>C p.L12S | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56261299; called by muse, mutect2, varscan2
- SSBP1 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 62/75 reads (83%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54682153; called by muse, mutect2, varscan2
- SSX5 | c.464C>T p.S155F (on ENST00000347757 / NM_175723.1; = p.S196F on NM_021015.4) | Missense Mutation (SNP) | VAF 54/60 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV61256375; called by muse, mutect2, varscan2
- STAC | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV56217105, COSV99829427; called by muse, mutect2, varscan2
- STON2 | c.1891G>A p.D631N (on ENST00000649389 / NM_001366849.2; = p.D574N on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV50845956; called by muse, mutect2, varscan2
- SUSD4 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59556060; called by muse, mutect2, varscan2
- SYN3 | c.1319G>A p.G440E | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); catalogued as COSV60513335, COSV60515237; called by muse, mutect2, varscan2
- SZT2 | c.3830C>T p.P1277L (on ENST00000634258 / NM_001365999.1; = p.P1220L on NM_015284.4) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs973840792, COSV65173840; called by muse, mutect2, varscan2
- SZT2 | c.4742C>T p.S1581L (on ENST00000634258 / NM_001365999.1; = p.S1524L on NM_015284.4) | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1168668932, COSV65173847; called by muse, mutect2, varscan2
- TARS1 | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as rs773821743, COSV54312003; called by muse, mutect2, varscan2
- TBATA | c.614A>T p.H205L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.163); catalogued as COSV100165089; called by muse, mutect2, varscan2
- TBC1D32 | c.2398C>T p.P800S | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.481); catalogued as rs909430979, COSV51543402; called by muse, mutect2, varscan2
- TBCD | c.2966C>T p.S989F | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1432652024, COSV62806940; called by muse, mutect2, varscan2
- TDRD5 | c.1126+1G>A p.X376_splice | Splice Site (SNP) | VAF 31/86 reads (36%) | catalogued as COSV54249299; called by muse, mutect2, varscan2
- TENM1 | c.4723G>A p.D1575N | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.244); catalogued as COSV64441216; called by muse, mutect2, varscan2
- TFCP2L1 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV55294702; called by muse, mutect2, varscan2
- TG | c.8002C>T p.P2668S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55091890; called by muse, mutect2, varscan2
- THSD4 | c.2832G>A p.M944I | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV55982443; called by muse, mutect2, varscan2
- THSD7B | c.2395C>T p.R799W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs375482277; called by muse, mutect2, varscan2
- THSD7B | c.3278G>A p.R1093K (on ENST00000272643; = p.R1091K on NM_001316349.2) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV99742586; called by muse, mutect2, varscan2
- TLE6 | c.1414G>A p.E472K (on ENST00000246112 / NM_001143986.2; = p.E349K on NM_024760.3) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1200790167, COSV53582858; called by muse, mutect2, varscan2
- TLL2 | c.2711C>T p.S904F | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1345815496, COSV63570687; called by muse, mutect2, varscan2
- TMEM144 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV56702675; called by muse, mutect2, varscan2
- TMEM200A | c.1293G>A p.M431I | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV51648640, COSV51660625; called by muse, mutect2, varscan2
- TMEM82 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65387992; called by muse, mutect2, varscan2
- TMLHE | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 5/117 reads (4%) | catalogued as COSV100544541; called by muse, mutect2
- TMPRSS4 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV71110251; called by muse, mutect2, varscan2
- TOP1 | c.608G>A p.W203* | Nonsense Mutation (SNP) | VAF 9/14 reads (64%) | catalogued as rs1167614758, COSV63695821; called by muse, mutect2, varscan2
- TRAV21 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as rs551533623; called by muse, mutect2, varscan2
- TRHDE | c.2006G>A p.R669K | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV53862884; called by muse, mutect2, varscan2
- TRHR | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61236186; called by muse, mutect2, varscan2
- TRIM58 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT tolerated (0.85); PolyPhen benign (0.021); catalogued as COSV63569854, COSV63572045; called by muse, mutect2, varscan2
- TSPOAP1 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV52116448; called by muse, mutect2, varscan2
- TTC1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 49/64 reads (77%) | SIFT tolerated (0.13); PolyPhen benign (0.283); catalogued as COSV51466547; called by muse, mutect2, varscan2
- TTLL10 | c.1205C>A p.T402N (on ENST00000379289 / NM_001130045.2; = p.T329N on NM_153254.3) | Missense Mutation (SNP) | VAF 98/217 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64961131; called by muse, mutect2, varscan2
- TTN | c.89129C>T p.S29710L (on ENST00000591111; = p.S22286L on NM_003319.4) | Missense Mutation (SNP) | VAF 27/53 reads (51%) | PolyPhen probably damaging (0.996); catalogued as rs794729536, COSV60299830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.54017G>A p.G18006E (on ENST00000591111; = p.G10582E on NM_003319.4) | Missense Mutation (SNP) | VAF 63/147 reads (43%) | PolyPhen probably damaging (1); catalogued as rs1559611400, COSV60214642; called by muse, mutect2, varscan2
- TTN | c.43304G>A p.W14435* (on ENST00000591111; = p.W7011* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 39/98 reads (40%) | catalogued as COSV60299882; called by muse, mutect2, varscan2
- TTN | c.18845G>A p.G6282E (on ENST00000591111; = p.G5355E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/114 reads (42%) | PolyPhen probably damaging (1); catalogued as COSV60299928; called by muse, mutect2, varscan2
- TTN | c.13736C>T p.P4579L (on ENST00000591111; = p.P3652L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | PolyPhen benign (0.131); catalogued as rs866936144, COSV60299936; called by muse, mutect2, varscan2
- TTN | c.7053G>A p.M2351I (on ENST00000591111; = p.M2305I on NM_003319.4) | Missense Mutation (SNP) | VAF 49/117 reads (42%) | PolyPhen benign (0.11); catalogued as COSV60299951; called by muse, mutect2, varscan2
- UBOX5 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV53906292; called by muse, mutect2, varscan2
- UBQLN3 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV61165439; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1606G>A p.G536S | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.261); catalogued as COSV51959739; called by muse, mutect2, varscan2
- UHRF1BP1L | c.860C>G p.S287C | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV54441989; called by muse, mutect2, varscan2
- USP32 | c.3922C>T p.P1308S | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56276263; called by muse, mutect2, varscan2
- USP6 | c.2732C>T p.T911I | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100002766; called by muse, mutect2, varscan2
- VARS1 | c.3359C>T p.S1120F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs866639021, COSV100791766; called by muse, mutect2, varscan2
- VN1R5 | c.700C>T p.L234F | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); catalogued as rs1301305071; called by muse, mutect2, varscan2
- VNN1 | c.772A>G p.M258V | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs774589624, COSV63390884; called by muse, mutect2, varscan2
- VWA7 | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV100991675; called by muse, mutect2, varscan2
- WAS | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV61920215; called by muse, mutect2, varscan2
- WDR7 | c.3509C>T p.S1170L | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54361775; called by muse, mutect2, varscan2
- WDR72 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV64752923; called by muse, mutect2
- WNK4 | c.1819G>T p.G607W | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs754654053, COSV55910456, COSV99889176; called by mutect2, varscan2
- WWC3 | c.2024C>T p.P675L | Missense Mutation (SNP) | VAF 97/116 reads (84%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV66506772; called by muse, mutect2, varscan2
- XKR6 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as COSV58658401; called by muse, mutect2, varscan2
- XKR7 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1482664633, COSV73813424; called by muse, mutect2, varscan2
- XYLT1 | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775881502, COSV54483124; called by muse, mutect2, varscan2
- ZBBX | c.2038G>A p.D680N | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56788773; called by muse, mutect2, varscan2
- ZBED9 | c.1595C>T p.S532F | Missense Mutation (SNP) | VAF 134/199 reads (67%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.205); catalogued as COSV101509076; called by muse, mutect2, varscan2
- ZFP2 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious (0.05); PolyPhen benign (0.172); catalogued as rs1274914484, COSV63726869; called by muse, mutect2, varscan2
- ZFPM2 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs867948316, COSV65875532; called by muse, mutect2, varscan2
- ZMYM6 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.739); catalogued as rs1195449317, COSV58185293; called by muse, mutect2, varscan2
- ZNF185 | c.1066G>A p.G356S | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV100248105; called by muse, mutect2, varscan2
- ZNF215 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV53493380; called by muse, mutect2, varscan2
- ZNF385B | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV61181114; called by muse, mutect2, varscan2
- ZNF493 | c.1738A>T p.T580S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.199); catalogued as rs769752780, COSV62751756; called by muse, mutect2, varscan2
- ZNF665 | c.1427C>T p.P476L (on ENST00000600412; = p.P541L on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/109 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV67217207; called by muse, mutect2, varscan2
- ZNF804A | c.1412A>T p.N471I | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV56468060; called by muse, mutect2
- ZNF862 | c.2859G>T p.M953I | Missense Mutation (SNP) | VAF 116/138 reads (84%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV56225830; called by muse, mutect2, varscan2
- ZSCAN10 | c.172G>A p.E58K (on ENST00000252463; = p.E113K on NM_032805.3) | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV52970450; called by muse, mutect2, varscan2
- ZSWIM3 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV54850981; called by muse, mutect2, varscan2
- CGB5 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CYFIP1 | c.2336C>T p.S779F | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DHX32 | c.151_153delinsAG p.R51Sfs*6 | Frame Shift Del (DEL) | VAF 38/133 reads (29%) | called by pindel, varscan2*
- GDF2 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- LDHA | c.911_931del p.V304_S310del | In Frame Del (DEL) | VAF 26/105 reads (25%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- TRAV12-1 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- ABAT | c.849G>A p.K283= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV51627612; called by muse, mutect2, varscan2
- ABAT | c.1443G>A p.R481= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs1237985824, COSV51627624; called by muse, mutect2, varscan2
- ABR | c.921C>T p.F307= (on ENST00000302538 / NM_021962.5; = p.F270= on NM_001092.5) | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99347311; called by muse, mutect2, varscan2
- ACAD10 | c.1029C>T p.V343= | Silent (SNP) | VAF 32/53 reads (60%) | catalogued as rs771448380, COSV58162391; called by muse, mutect2, varscan2
- ACSM2A | c.1437G>A p.E479= (on ENST00000219054; = p.E400= on NM_001308169.2) | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs149737523, COSV54587379; called by muse, mutect2, varscan2
- ACTN3 | c.1914G>A p.R638= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs1487135898, COSV59750348; called by muse, mutect2, varscan2
- ADAM29 | c.744G>A p.L248= | Silent (SNP) | VAF 44/71 reads (62%) | catalogued as COSV63667531; called by muse, mutect2, varscan2
- ADAM7 | c.954C>T p.I318= | Silent (SNP) | VAF 46/123 reads (37%) | catalogued as COSV51545823, COSV99442708; called by muse, mutect2, varscan2
- ADH4 | c.711G>A p.K237= | Silent (SNP) | VAF 40/54 reads (74%) | catalogued as COSV55502162; called by muse, mutect2, varscan2
- AFAP1L2 | c.2238G>A p.K746= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV58418170; called by muse, mutect2, varscan2
- AHDC1 | c.2340T>C p.H780= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as rs1035113580, COSV55941983; called by muse, mutect2, varscan2
- ANK1 | c.234G>A p.G78= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV55893544; called by muse, mutect2, varscan2
- AOC3 | c.1767G>A p.L589= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as rs1380748638, COSV53828545; called by muse, mutect2, varscan2
- AOX1 | c.2961C>T p.S987= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as COSV65984368, COSV65984650; called by muse, mutect2, varscan2
- AQP9 | c.318G>T p.V106= | Silent (SNP) | VAF 53/156 reads (34%) | catalogued as COSV54968764, COSV54970252; called by muse, mutect2, varscan2
- ARC | c.942G>A p.V314= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs766350532, COSV63079659; called by muse, mutect2, varscan2
- ARHGAP20 | c.924C>T p.I308= | Silent (SNP) | VAF 69/176 reads (39%) | catalogued as rs1350697814, COSV52818156; called by muse, mutect2, varscan2
- ARHGAP26 | c.2418C>T p.I806= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV50839424; called by muse, mutect2, varscan2
- ARPP21 | c.2112G>A p.V704= | Silent (SNP) | VAF 54/115 reads (47%) | catalogued as COSV51794098; called by muse, mutect2, varscan2
- ATP2A2 | c.1692C>T p.A564= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV100428333; called by muse, mutect2, varscan2
- ATP2A3 | c.2673C>T p.F891= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1486859115, COSV59234524; called by muse, mutect2, varscan2
- C10orf53 | c.387C>T p.F129= | Silent (SNP) | VAF 46/117 reads (39%) | catalogued as COSV65109498; called by muse, mutect2, varscan2
- C10orf62 | c.540G>A p.K180= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as COSV65705069, COSV65705534; called by muse, mutect2, varscan2
- C12orf50 | c.933C>T p.A311= | Silent (SNP) | VAF 41/65 reads (63%) | catalogued as rs560982989, COSV53898361; called by muse, mutect2, varscan2
- C1orf94 | c.1710C>A p.P570= (on ENST00000488417 / NM_001134734.2; = p.P380= on NM_032884.5) | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs766468295, COSV64915470; called by muse, mutect2, varscan2
- CACNA1H | c.6267G>A p.E2089= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs1228202243, COSV99326241; called by muse, mutect2, varscan2
- CACNA1I | c.4749C>T p.I1583= | Silent (SNP) | VAF 35/47 reads (74%) | catalogued as COSV60817380; called by muse, mutect2, varscan2
- CATSPER1 | c.672C>T p.H224= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV100375515; called by muse, mutect2, varscan2
- CCKBR | c.1030C>T p.L344= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV58104827; called by muse, mutect2, varscan2
- CCN3 | c.1032C>T p.F344= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as rs898382754, COSV52383285, COSV52384279; called by muse, mutect2, varscan2
- CCT8L2 | c.60G>A p.R20= | Silent (SNP) | VAF 21/27 reads (78%) | catalogued as rs909175734, COSV63463657, COSV99068271; called by muse, mutect2, varscan2
- CD59 | c.96T>C p.P32= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV60919856; called by muse, mutect2, varscan2
- CHRM3 | c.945C>T p.F315= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs201978988, COSV55101567; called by muse, mutect2, varscan2
- CHRNA2 | c.570C>T p.F190= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as rs1418089410, COSV53559135; called by muse, mutect2, varscan2
- CILP | c.837G>A p.K279= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV56027464; called by muse, mutect2, varscan2
- CPXM2 | c.1824C>T p.S608= | Silent (SNP) | VAF 55/110 reads (50%) | catalogued as COSV53869797; called by muse, mutect2, varscan2
- CREB5 | c.1236G>A p.Q412= (on ENST00000357727 / NM_182898.4; = p.Q405= on NM_004904.3) | Silent (SNP) | VAF 23/25 reads (92%) | catalogued as rs1285068567, COSV63227773; called by muse, mutect2, varscan2
- CRHR2 | c.840C>T p.F280= | Silent (SNP) | VAF 62/73 reads (85%) | catalogued as rs149909822; called by muse, mutect2, varscan2
- CTCFL | c.765A>G p.G255= | Silent (SNP) | VAF 47/114 reads (41%) | catalogued as COSV54778292; called by muse, mutect2, varscan2
- CUX2 | c.627C>T p.V209= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as COSV55645700; called by muse, mutect2, varscan2
- CUX2 | c.1149C>T p.S383= | Silent (SNP) | VAF 23/31 reads (74%) | catalogued as rs1315522941, COSV55631674; called by muse, mutect2, varscan2
- CYB5D2 | c.114C>T p.F38= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV56801938; called by muse, mutect2, varscan2
- CYP11B1 | c.631C>T p.L211= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99454337; called by muse, mutect2, varscan2
- CYP4F11 | c.210G>A p.T70= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as rs770850483, COSV56126788, COSV56129225; called by muse, mutect2, varscan2
- CYP4F2 | c.1084C>T p.L362= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV50002585; called by muse, mutect2, varscan2
- DCAF4 | c.504C>T p.A168= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100611181, COSV62320422; called by muse, mutect2, varscan2
- DCLK3 | c.1218C>T p.I406= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as COSV69363287, COSV69364530; called by muse, mutect2, varscan2
- DDX60 | c.1347C>T p.S449= | Silent (SNP) | VAF 41/54 reads (76%) | catalogued as rs1384371456, COSV67098836; called by muse, mutect2, varscan2
- DNAH10 | c.1260G>A p.V420= (on ENST00000409039; = p.V359= on NM_207437.3) | Silent (SNP) | VAF 20/27 reads (74%) | catalogued as COSV69000158; called by muse, mutect2, varscan2
- DNAH3 | c.10011G>A p.T3337= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as rs367808003; called by muse, mutect2, varscan2
- DNAH7 | c.8967G>A p.L2989= | Silent (SNP) | VAF 54/122 reads (44%) | catalogued as COSV56782296; called by muse, mutect2, varscan2
- DNAI1 | c.855C>T p.I285= | Silent (SNP) | VAF 39/53 reads (74%) | catalogued as COSV54284170; called by muse, mutect2, varscan2
- DOCK1 | c.2020T>C p.L674= | Silent (SNP) | VAF 55/132 reads (42%) | catalogued as COSV54756962; called by muse, mutect2, varscan2
- DYSF | c.4179G>A p.R1393= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV50549900; called by muse, mutect2, varscan2
- DYTN | c.1455G>A p.E485= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs746423667, COSV71752906; called by muse, mutect2, varscan2
- EFCAB5 | c.3855G>A p.Q1285= | Silent (SNP) | VAF 40/60 reads (67%) | catalogued as COSV57928691, COSV57936012; called by muse, mutect2, varscan2
- EGFLAM | c.3018G>A p.V1006= (on ENST00000354891 / NM_001205301.2; = p.V998= on NM_152403.4) | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV59315148; called by muse, mutect2, varscan2
- EPHA6 | c.1509G>A p.V503= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs866564290, COSV67591379; called by muse, mutect2, varscan2
- ERICH3 | c.1059C>T p.F353= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs769875646, COSV58607407; called by muse, mutect2, varscan2
- ETV4 | c.765G>T p.A255= | Silent (SNP) | VAF 35/38 reads (92%) | catalogued as rs760833600, COSV100081661, COSV60045327; called by muse, mutect2, varscan2
- FAM83B | c.1023G>A p.G341= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as COSV60926131; called by muse, mutect2, varscan2
- FASN | c.2283C>T p.I761= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as rs141668388; called by muse, varscan2
- FAT4 | c.13477C>T p.L4493= | Silent (SNP) | VAF 44/55 reads (80%) | catalogued as COSV58705075; called by muse, mutect2, varscan2
- FMO2 | c.141G>A p.V47= | Silent (SNP) | VAF 45/118 reads (38%) | catalogued as COSV52950038; called by muse, mutect2, varscan2
- FNDC3B | c.3081C>T p.S1027= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV61045071; called by muse, mutect2, varscan2
- FRK | c.1173C>T p.H391= | Silent (SNP) | VAF 39/53 reads (74%) | catalogued as rs143648469; called by muse, mutect2, varscan2
- FRMPD2 | c.3279C>T p.F1093= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs549855862; called by mutect2, varscan2
- FTCD | c.897G>A p.R299= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV52428422, COSV52429261; called by muse, mutect2, varscan2
- G6PD | c.1143C>T p.F381= | Silent (SNP) | VAF 31/41 reads (76%) | catalogued as COSV63704303; called by muse, mutect2, varscan2
- GJA1 | c.747G>A p.A249= | Silent (SNP) | VAF 25/35 reads (71%) | catalogued as rs765163958, COSV56997060, COSV56999095; called by muse, mutect2, varscan2
- GJB4 | c.120G>A p.A40= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs764338808, COSV58355691, COSV58356339; called by muse, mutect2, varscan2
- GKAP1 | c.852G>A p.K284= | Silent (SNP) | VAF 32/48 reads (67%) | catalogued as COSV100897353, COSV104426889; called by muse, mutect2, varscan2
- GREB1 | c.5307C>T p.I1769= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs564155213, COSV52195131; called by muse, mutect2, varscan2
- GUCY2D | c.1695C>T p.F565= | Silent (SNP) | VAF 42/53 reads (79%) | catalogued as COSV54698435; called by muse, mutect2, varscan2
- HEPH | c.204G>A p.R68= (on ENST00000343002; = p.R122= on NM_138737.5) | Silent (SNP) | VAF 33/39 reads (85%) | catalogued as rs1247661418, COSV57970855; called by muse, mutect2, varscan2
- HHLA2 | c.204C>T p.S68= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV63319602; called by muse, mutect2, varscan2
- IGHV3-23 | c.138C>T p.F46= | Silent (SNP) | VAF 67/381 reads (18%) | catalogued as rs547509640; called by muse, mutect2, varscan2
- IL12RB1 | c.882G>A p.K294= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV59099061; called by muse, mutect2, varscan2
- IL18R1 | c.1380C>T p.L460= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs1346718183, COSV52126973; called by muse, mutect2, varscan2
- INTS7 | c.2532C>T p.F844= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as rs902646885, COSV65345168; called by muse, mutect2, varscan2
- ITGB2 | c.48C>T p.S16= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1441543050, COSV100185509; called by muse, mutect2
- JAKMIP2 | c.1605G>A p.Q535= | Silent (SNP) | VAF 77/159 reads (48%) | catalogued as COSV54614145; called by muse, mutect2, varscan2
- KCNH5 | c.1056G>T p.L352= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV100525023; called by muse, mutect2, varscan2
- KIF26A | c.2316C>T p.C772= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs779987066, COSV59470082; called by muse, varscan2
- KMT2A | c.11340C>T p.F3780= | Silent (SNP) | VAF 29/50 reads (58%) | catalogued as COSV63291693; called by muse, mutect2, varscan2
- KRT40 | c.639G>A p.V213= | Silent (SNP) | VAF 67/85 reads (79%) | catalogued as COSV66696874; called by muse, mutect2, varscan2
- LAIR2 | c.345C>T p.F115= | Silent (SNP) | VAF 46/59 reads (78%) | catalogued as COSV56621134; called by muse, mutect2, varscan2
- LGALS14 | c.120C>T p.F40= | Silent (SNP) | VAF 30/36 reads (83%) | catalogued as rs977917052, COSV62373203; called by muse, mutect2, varscan2
- LRRC6 | c.453G>A p.E151= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV51546910; called by muse, mutect2, varscan2
- M1AP | c.69G>A p.R23= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV51847776; called by muse, mutect2, varscan2
- MAGEB1 | c.447C>T p.I149= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs1405974420, COSV66776500; called by muse, mutect2, varscan2
- MC2R | c.541C>T p.L181= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV59620192; called by muse, mutect2, varscan2
- MCM2 | c.1500C>T p.F500= | Silent (SNP) | VAF 47/99 reads (47%) | catalogued as rs757903789, COSV54033243, COSV54037018; called by muse, mutect2, varscan2
- ME1 | c.1200G>A p.R400= | Silent (SNP) | VAF 32/145 reads (22%) | catalogued as rs142365257, COSV63842082; called by muse, mutect2, varscan2
- MGAM | c.2094C>T p.S698= | Silent (SNP) | VAF 131/154 reads (85%) | catalogued as COSV72075270; called by muse, mutect2, varscan2
- MUC16 | c.25953G>A p.G8651= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as COSV67489141, COSV67490200; called by muse, mutect2, varscan2
- MYH7 | c.2148G>A p.G716= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV62519504; called by muse, mutect2, varscan2
- MYO7A | c.1437G>A p.L479= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs544245959, COSV68686815; called by muse, mutect2, varscan2
- NCKAP1L | c.1386C>T p.F462= | Silent (SNP) | VAF 42/60 reads (70%) | catalogued as rs781431352, COSV53206798, COSV53211572; called by muse, mutect2, varscan2
- NECAB2 | c.1005C>T p.I335= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs1567681230, COSV59419306, COSV59422995; called by muse, mutect2, varscan2
- NFASC | c.1986C>T p.V662= (on ENST00000339876 / NM_001378329.1; = p.V658= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as rs751878525, COSV58377969; called by muse, mutect2, varscan2
- NFIX | c.273C>T p.F91= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV62175392; called by muse, mutect2, varscan2
- NID1 | c.1326C>T p.I442= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV51627855; called by muse, mutect2, varscan2
- NLRP9 | c.1449G>A p.Q483= | Silent (SNP) | VAF 76/104 reads (73%) | catalogued as COSV60467184; called by muse, mutect2, varscan2
- NMUR2 | c.1247G>A p.*416= | Silent (SNP) | VAF 24/31 reads (77%) | catalogued as COSV54922083; called by muse, mutect2, varscan2
- NOXRED1 | c.372C>T p.I124= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs1282703651, COSV53628984; called by muse, mutect2, varscan2
- NPY2R | c.394C>T p.L132= | Silent (SNP) | VAF 27/36 reads (75%) | catalogued as rs574234226, COSV61527409; called by muse, mutect2, varscan2
- NUB1 | c.1179C>T p.L393= | Silent (SNP) | VAF 139/165 reads (84%) | catalogued as COSV63427541; called by muse, mutect2, varscan2
- NUCB1 | c.30C>T p.L10= | Silent (SNP) | VAF 21/27 reads (78%) | catalogued as COSV54388076; called by muse, mutect2, varscan2
- NUP210L | c.1314C>T p.S438= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as COSV55156265; called by muse, mutect2, varscan2
- NYAP2 | c.1083G>A p.T361= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs780896106, COSV56003534; called by muse, mutect2, varscan2
- OLFML1 | c.45C>T p.F15= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs756840771, COSV61403952; called by muse, mutect2, varscan2
- OR10A6 | c.786C>T p.P262= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV100564225; called by muse, mutect2, varscan2
- OR10A6 | c.117G>A p.L39= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as COSV59165918; called by muse, mutect2, varscan2
- OR1A2 | c.618C>T p.F206= | Silent (SNP) | VAF 88/218 reads (40%) | called by muse, mutect2, varscan2
- OR1G1 | c.531C>T p.F177= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as COSV100187478; called by muse, mutect2, varscan2
- OR3A3 | c.624C>T p.L208= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV52168431, COSV52168945; called by muse, mutect2, varscan2
- OR4B1 | c.330C>T p.I110= | Silent (SNP) | VAF 54/147 reads (37%) | catalogued as rs267602911, COSV58883299; called by muse, mutect2, varscan2
- OR4C13 | c.615C>T p.C205= | Silent (SNP) | VAF 62/144 reads (43%) | catalogued as rs1565189921, COSV73648900; called by muse, mutect2, varscan2
- OR51B5 | c.27C>T p.P9= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs199973004, COSV56177139; called by muse, mutect2
- OR51I1 | c.318C>T p.I106= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs745717951, COSV66509045; called by muse, mutect2, varscan2
- OR52E2 | c.36C>T p.S12= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV58613461; called by muse, mutect2, varscan2
- OR5AR1 | c.624C>T p.F208= | Silent (SNP) | VAF 67/126 reads (53%) | catalogued as COSV57255179; called by muse, mutect2, varscan2
- OR6K2 | c.729C>T p.V243= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs1373077647, COSV62744134; called by muse, mutect2, varscan2
- OR8D2 | c.312C>T p.F104= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as rs139872826, COSV62489012; called by muse, mutect2, varscan2
- OR8S1 | c.456C>A p.G152= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100043426; called by muse, mutect2, varscan2
- PATL1 | c.1239C>T p.V413= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV55692431, COSV55693375; called by muse, mutect2, varscan2
- PCDH10 | c.2064G>A p.G688= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs1298496678, COSV52102760; called by muse, mutect2, varscan2
- PCDHA6 | c.45C>T p.L15= | Silent (SNP) | VAF 59/143 reads (41%) | catalogued as COSV65350884; called by muse, mutect2, varscan2
- PCDHA9 | c.1662C>T p.F554= | Silent (SNP) | VAF 55/147 reads (37%) | catalogued as rs782760687, COSV65329339; called by muse, mutect2, varscan2
- PCDHAC1 | c.1644G>A p.R548= | Silent (SNP) | VAF 51/129 reads (40%) | catalogued as COSV53856476; called by muse, mutect2, varscan2
- PCDHB7 | c.1293G>A p.L431= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV50801056; called by muse, mutect2, varscan2
- PCDHGA3 | c.144C>T p.I48= | Silent (SNP) | VAF 70/186 reads (38%) | catalogued as rs754808139, COSV54018446; called by muse, mutect2, varscan2
- PCDHGB2 | c.675G>A p.T225= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV53901307; called by muse, mutect2, varscan2
- PGR | c.2262T>G p.S754= | Silent (SNP) | VAF 82/191 reads (43%) | catalogued as COSV54809624; called by muse, mutect2, varscan2
- PHLDA1 | c.1182C>T p.L394= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV56998122; called by muse, mutect2, varscan2
- PLBD1 | c.252C>T p.I84= | Silent (SNP) | VAF 32/39 reads (82%) | catalogued as COSV53695880; called by muse, mutect2, varscan2
- PLCL1 | c.2478T>A p.V826= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV70868770; called by muse, mutect2, varscan2
- PMPCA | c.1404C>T p.L468= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV65510892; called by muse, mutect2, varscan2
- PRDX6 | c.318G>A p.R106= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as COSV61166195; called by muse, mutect2, varscan2
- PROM2 | c.996C>A p.V332= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV58300456; called by muse, mutect2, varscan2
- PSG3 | c.504C>T p.T168= | Silent (SNP) | VAF 114/150 reads (76%) | catalogued as rs767838615, COSV59503404; called by muse, mutect2, varscan2
- PTPRK | c.951C>T p.I317= | Silent (SNP) | VAF 71/90 reads (79%) | catalogued as COSV63887677; called by muse, mutect2, varscan2
- PYROXD2 | c.363C>T p.P121= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV65331301; called by muse, mutect2, varscan2
- RAB6B | c.405G>A p.Q135= | Silent (SNP) | VAF 49/112 reads (44%) | catalogued as COSV53315458; called by muse, mutect2, varscan2
- RIN3 | c.1599C>T p.S533= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV53646565; called by muse, mutect2, varscan2
- SCN10A | c.5160G>A p.V1720= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as rs1412305153, COSV71862493; called by muse, mutect2, varscan2
- SERPINA5 | c.474C>T p.F158= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV61574921; called by muse, mutect2, varscan2
- SGTA | c.57C>T p.L19= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV55595564; called by muse, mutect2, varscan2
- SLC39A6 | c.2247C>T p.I749= | Silent (SNP) | VAF 39/55 reads (71%) | catalogued as rs747730811, COSV52367880; called by muse, mutect2, varscan2
- SLC47A1 | c.1263C>A p.L421= | Silent (SNP) | VAF 45/68 reads (66%) | catalogued as COSV54501932; called by muse, mutect2, varscan2
- SLC9A4 | c.1794C>T p.S598= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV54838439; called by muse, mutect2, varscan2
- SLCO5A1 | c.420C>T p.I140= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV52666837, COSV99479342, COSV99481399; called by muse, mutect2, varscan2
- SMYD5 | c.201C>T p.Y67= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV50265633; called by muse, mutect2, varscan2
- SP140 | c.2007G>A p.R669= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs1421401359, COSV59447563; called by muse, mutect2, varscan2
- SPEG | c.918C>T p.S306= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV100403038; called by muse, mutect2
- STX1B | c.648G>A p.V216= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV52681905; called by muse, mutect2, varscan2
- TBATA | c.615C>T p.H205= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs1182099537, COSV100165088; called by muse, mutect2, varscan2
- TC2N | c.813C>T p.P271= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV61748047; called by muse, mutect2, varscan2
- TELO2 | c.486C>T p.A162= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV51980800; called by muse, mutect2, varscan2
- TMEM145 | c.558C>T p.F186= | Silent (SNP) | VAF 27/33 reads (82%) | catalogued as COSV56623939; called by muse, mutect2, varscan2
- TMLHE | c.900A>G p.E300= | Silent (SNP) | VAF 5/120 reads (4%) | catalogued as rs782372493, COSV100544540; called by muse, mutect2
- TRIM29 | c.1500G>A p.K500= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV59281993; called by muse, mutect2, varscan2
- TTN | c.22536G>A p.L7512= (on ENST00000591111; = p.L6585= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as rs1255955033, COSV60299915; called by muse, mutect2, varscan2
- UGT3A1 | c.1512G>A p.G504= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV57096923; called by muse, mutect2, varscan2
- USP8 | c.186A>C p.L62= | Silent (SNP) | VAF 54/137 reads (39%) | catalogued as COSV56164186; called by muse, mutect2, varscan2
- YWHAQ | c.597C>T p.A199= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as rs1170546582, COSV53004570; called by muse, mutect2, varscan2
- ZBED9 | c.2172G>A p.G724= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV71729215; called by muse, mutect2, varscan2
- ZFAND2B | c.531C>T p.A177= | Silent (SNP) | VAF 46/117 reads (39%) | catalogued as COSV54699691; called by muse, mutect2, varscan2
- ZFHX4 | c.2064G>A p.R688= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV51492146, COSV99257002; called by muse, mutect2, varscan2
- ZNF331 | c.703A>C p.R235= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as COSV53479557; called by muse, mutect2, varscan2
- ZNF764 | c.384C>T p.A128= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs748875795, COSV53222486; called by muse, mutect2, varscan2
- ZNF81 | c.1680G>A p.G560= | Silent (SNP) | VAF 36/46 reads (78%) | catalogued as COSV58578315; called by muse, mutect2, varscan2
- ANKFN1 | c.-1C>T | 5'UTR (SNP) | VAF 34/107 reads (32%) | catalogued as COSV100592984; called by muse, mutect2, varscan2
- CDKL1 | c.171+17433C>T | Intron (SNP) | VAF 18/40 reads (45%) | catalogued as COSV99367147; called by muse, mutect2, varscan2
- DLG2 | c.205-65804G>A | Intron (SNP) | VAF 85/235 reads (36%) | catalogued as COSV99711987; called by muse, mutect2, varscan2
- FRMPD2B | n.696C>T | RNA (SNP) | VAF 28/176 reads (16%) | catalogued as rs1245401559; called by mutect2, varscan2
- MGAM | c.4618+363G>A | Intron (SNP) | VAF 39/42 reads (93%) | catalogued as rs561932269, COSV101527342; called by muse, mutect2, varscan2
- MIR524 | n.48G>A | RNA (SNP) | VAF 59/79 reads (75%) | catalogued as rs1163023757; called by muse, mutect2, varscan2
- MTCL1 | c.2968-3158G>A | Intron (SNP) | VAF 41/178 reads (23%) | catalogued as COSV60411017; called by muse, mutect2, varscan2
- PWWP3A | chr19:1376561 C>T | 3'Flank (SNP) | VAF 28/72 reads (39%) | catalogued as rs1403189140, COSV60904754; called by muse, mutect2, varscan2
- SLC22A17 | n.746C>T | RNA (SNP) | VAF 15/34 reads (44%) | catalogued as COSV99248433; called by muse, mutect2, varscan2
- SMYD5 | c.-2A>G | 5'UTR (SNP) | VAF 65/207 reads (31%) | catalogued as COSV99242655; called by muse, mutect2, varscan2
- SNX29P2 | n.1055G>A | RNA (SNP) | VAF 18/50 reads (36%) | catalogued as rs763737038; called by muse, mutect2, varscan2
- SPATA8 | n.868G>A | RNA (SNP) | VAF 54/105 reads (51%) | catalogued as rs200464383, COSV60704341; called by muse, mutect2, varscan2
- SSPOP | n.2350C>T | RNA (SNP) | VAF 35/41 reads (85%) | catalogued as COSV50489141; called by muse, mutect2, varscan2
- TTN | c.34354+559C>T | Intron (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100590032; called by muse, mutect2, varscan2
- TTN | c.10303+1323G>T | Intron (SNP) | VAF 36/90 reads (40%) | catalogued as COSV60299946; called by muse, mutect2, varscan2
- UVSSA | c.*8710C>T | 3'UTR (SNP) | VAF 113/213 reads (53%) | catalogued as rs148105783; called by muse, mutect2, varscan2
- ZSCAN31 | c.-2G>A | 5'UTR (SNP) | VAF 46/159 reads (29%) | catalogued as COSV100716831; called by muse, mutect2, varscan2
